Somatic mutation profile of tumor specimen TCGA-UY-A78P-01A (aliquot TCGA-UY-A78P-01A-12D-A364-08) from TCGA case TCGA-UY-A78P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 78.6 years (28,719 days).
Specimen TCGA-UY-A78P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac0e8e00-7ed0-462c-bc8a-83a5a38c5d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A78P-11A (Solid Tissue Normal), aliquot TCGA-UY-A78P-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caa62b6e-f021-453e-95b9-2fc65ba4fc92

The open-access MAF lists 312 somatic variants for this specimen: 229 protein-altering or splice-affecting, 75 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 75, Nonsense Mutation 23, Intron 6, Splice Site 4, Splice Region 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>C p.M1043I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as CM126698, COSV55873376, COSV55878974, COSV55898229; called by muse, mutect2, varscan2
- ACADS | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs766747544, COSV54368189; called by muse, mutect2, varscan2
- ADGRA2 | c.1333C>A p.H445N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59443844; called by muse, mutect2, varscan2
- ADGRL2 | c.3389C>G p.S1130C (on ENST00000370717 / NM_001366005.1; = p.S1117C on NM_012302.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1341324062, COSV54669020, COSV99589788; called by muse, mutect2, varscan2
- AGL | c.3091C>G p.Q1031E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV54053161; called by muse, mutect2, varscan2
- AKAP11 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99213834, COSV99214374; called by muse, mutect2
- AKAP6 | c.3743C>T p.S1248F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV55215144; called by muse, mutect2, varscan2
- ANGPTL6 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV99464013; called by muse, mutect2, varscan2
- ANK3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55060164; called by muse, mutect2, varscan2
- ANKIB1 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1197761777, COSV56061909; called by muse, mutect2, varscan2
- API5 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.348); catalogued as COSV101124609; called by muse, mutect2
- APPL1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1213897253, COSV55699788; called by muse, mutect2
- ARHGAP26 | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.879); catalogued as COSV50830269; called by muse, mutect2, varscan2
- ATP2A1 | c.1869G>C p.M623I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV62869622; called by muse, mutect2, varscan2
- ATP6V1A | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs111894180, COSV56362428; called by muse, mutect2, varscan2
- BARX2 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs906881234, COSV99859051; called by muse, mutect2
- BRAF | c.1844G>A p.R615K (on ENST00000288602 / NM_001374244.1; = p.R575K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV56137419; called by muse, mutect2
- BTBD10 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53399216; called by muse, mutect2, varscan2
- BTN2A1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57002527; called by muse, mutect2, varscan2
- C1QTNF7 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV54852962; called by muse, mutect2, varscan2
- C1orf116 | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63944133; called by muse, mutect2, varscan2
- C6orf226 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100491818, COSV59035549; called by muse, mutect2, varscan2
- CASP8AP2 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99387600; called by muse, mutect2
- CCDC134 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV99079668, COSV99740857; called by muse, mutect2
- CCR2 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52748850; called by muse, mutect2, varscan2
- CD207 | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as rs1219612738, COSV101338597; called by muse, mutect2, varscan2
- CD34 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV60413118, COSV60415617; called by muse, mutect2, varscan2
- CDC37 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV55768501; called by muse, mutect2, varscan2
- CFAP251 | c.3406C>A p.L1136I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56610809; called by muse, mutect2
- CFAP91 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56341304; called by muse, mutect2, varscan2
- CHAF1B | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58440208; called by muse, mutect2, varscan2
- CHD1 | c.2627C>G p.A876G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52340732; called by muse, mutect2, varscan2
- CHD2 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67709867; called by muse, mutect2, varscan2
- CLCN6 | c.2103G>C p.E701D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.121); catalogued as COSV56740373; called by muse, mutect2
- CLMN | c.569T>G p.I190S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100112976; called by muse, mutect2
- CLVS2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51563350, COSV99252287; called by muse, mutect2
- CNOT1 | c.3436C>T p.H1146Y | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55317268; called by muse, mutect2, varscan2
- CRELD1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.139); catalogued as rs755981922, CM108486, COSV55977319; called by muse, mutect2, varscan2
- CRYBG2 | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257507610, COSV57486264; called by muse, mutect2, varscan2
- CYLC1 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61412500; called by muse, mutect2, varscan2
- CYP3A5 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs765108001, COSV56120263; ClinVar: not provided; called by muse, mutect2, varscan2
- CYP4A22 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV53740577; called by muse, mutect2, varscan2
- CYP7B1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV59589248; called by muse, mutect2, varscan2
- CYSTM1 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV55834729; called by muse, mutect2, varscan2
- DACH1 | c.2067G>C p.K689N (on ENST00000619232 / NM_001366712.1; = p.K435N on NM_004392.6) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57501602; called by muse, mutect2, varscan2
- DAZL | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51712959; called by muse, mutect2, varscan2
- DCC | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs145416326, COSV59128591; called by muse, mutect2
- DCN | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV50007256; called by muse, mutect2
- DCST1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV55059672; called by muse, mutect2, varscan2
- DCUN1D2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV60261421; called by muse, mutect2, varscan2
- DDIAS | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61272286; called by muse, mutect2, varscan2
- DEF8 | c.319G>C p.E107Q (on ENST00000268676 / NM_207514.3; = p.E46Q on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV51919349; called by muse, mutect2, varscan2
- DGKD | c.1019G>A p.R340K (on ENST00000264057 / NM_152879.3; = p.R296K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV51032691, COSV51050501; called by muse, mutect2, varscan2
- DIDO1 | c.4459G>C p.E1487Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56623536; called by muse, mutect2, varscan2
- DNAJC30 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV56095094; called by muse, mutect2, varscan2
- DOCK1 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99732987; called by muse, mutect2
- DOCK10 | c.5194G>A p.E1732K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777581178, COSV51348670; called by muse, mutect2, varscan2
- DOCK10 | c.2824G>T p.D942Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1444286929, COSV51408347; called by muse, mutect2, varscan2
- EGFL6 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs746377752, COSV63633997; called by muse, mutect2, varscan2
- ERBB3 | c.2374C>A p.L792M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV57249223, COSV57254480; called by muse, mutect2, varscan2
- FAM217A | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51160304; called by muse, mutect2, varscan2
- FAM47A | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV60497090; called by muse, mutect2, varscan2
- FANCM | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV57501605; called by muse, mutect2, varscan2
- FAT4 | c.8802C>G p.I2934M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as COSV58672765, COSV58687691, COSV58713219; called by muse, mutect2, varscan2
- FLG | c.4795G>C p.D1599H | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64242449; called by muse, mutect2, varscan2
- FN1 | c.6103C>G p.Q2035E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.477); catalogued as COSV60553954; called by muse, mutect2, varscan2
- FTSJ3 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100835090; called by muse, mutect2, varscan2
- GABRE | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64819837; called by muse, mutect2
- GDF3 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.309); catalogued as rs1476673248, COSV100325409; called by muse, mutect2
- GH2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs773623624, COSV60426741; called by muse, mutect2, varscan2
- GK2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV62626996; called by muse, mutect2, varscan2
- GOLGA1 | c.2123G>C p.C708S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.998); catalogued as COSV52346883, COSV99414627; called by muse, mutect2, varscan2
- GOLGA8A | c.1702G>C p.E568Q (on ENST00000432566; = p.E540Q on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62169852; called by muse, mutect2, varscan2
- GON4L | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55194613; called by muse, mutect2, varscan2
- GPS2 | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59750013; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2, varscan2
- HCK | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV52943027; called by muse, mutect2, varscan2
- HEATR6 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV51746119; called by muse, varscan2
- HMCN1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs531770127, COSV54903513; called by muse, mutect2, varscan2
- HPS3 | c.885-1G>C p.X295_splice | Splice Site (SNP) | VAF 13/116 reads (11%) | catalogued as COSV56054668; called by muse, mutect2, varscan2
- HPSE2 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.925); catalogued as COSV65189897; called by muse, mutect2, varscan2
- HS3ST5 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV57141654; called by muse, mutect2, varscan2
- HUS1B | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57865428; called by muse, mutect2, varscan2
- IFT20 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV56878816; called by muse, mutect2, varscan2
- IQCC | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV99356812; called by muse, mutect2
- IQSEC3 | c.2694C>G p.F898L (on ENST00000538872 / NM_001170738.2; = p.F595L on NM_015232.1) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV58285303; called by muse, mutect2, varscan2
- IZUMO2 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53229401, COSV53230185; called by muse, mutect2
- KAT14 | c.2105C>G p.S702* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100890114, COSV66609313; called by muse, mutect2, varscan2
- KATNAL2 | c.992C>G p.S331* (on ENST00000356157 / NM_001353899.1; = p.S259* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99798286; called by muse, mutect2, varscan2
- KCNK13 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs770204298, COSV56413418; called by muse, mutect2, varscan2
- KCNQ5 | c.2592G>T p.W864C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59661621; called by muse, mutect2
- KDM6A | c.3182C>G p.S1061* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV65037520; called by muse, mutect2, varscan2
- KIFAP3 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1226533594, COSV63034226; called by muse, mutect2, varscan2
- KL | c.2367C>A p.F789L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV66308893, COSV66309020; called by muse, mutect2, varscan2
- KMT2C | c.12764C>G p.S4255* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100076976; called by muse, mutect2
- L3MBTL4 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99531372; called by muse, mutect2
- LAMB2 | c.2002C>G p.L668V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1194112845, COSV59733956; called by muse, mutect2, varscan2
- LCE1C | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV64218480; called by muse, mutect2, varscan2
- LEO1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55175916; called by muse, mutect2, varscan2
- LRRC8C | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1174180123, COSV64998350; called by muse, mutect2
- LSM11 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53848313; called by muse, mutect2, varscan2
- LTA4H | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344537884, COSV57382681; called by muse, mutect2, varscan2
- LTN1 | c.4015C>G p.Q1339E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV63733917; called by muse, mutect2, varscan2
- MAPK6 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.954); catalogued as COSV55930097; called by muse, mutect2, varscan2
- MAPK8IP3 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV51720917; called by muse, mutect2, varscan2
- MARCHF7 | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52029004; called by muse, mutect2, varscan2
- MAST4 | c.4184C>T p.S1395L (on ENST00000403625 / NM_001164664.2; = p.S1206L on NM_015183.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55126979; called by muse, mutect2, varscan2
- MBD6 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV63074706; called by muse, mutect2, varscan2
- MDN1 | c.9063G>C p.W3021C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65522368; called by muse, mutect2, varscan2
- MED13 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs199889415; called by muse, mutect2, varscan2
- MIOS | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60768632; called by muse, mutect2, varscan2
- MLIP | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV51430553; called by muse, mutect2, varscan2
- MLXIP | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778593659, COSV100039193; called by muse, mutect2
- MPDZ | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59942799; called by muse, mutect2, varscan2
- MSRA | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs891281233, COSV100413784; called by muse, mutect2
- MTFR2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV63079208; called by muse, mutect2, varscan2
- MUTYH | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100588208; called by muse, mutect2
- MYH7 | c.4953+1G>C p.X1651_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV62519703; called by muse, mutect2, varscan2
- MYO1D | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV59013831; called by muse, mutect2
- MYT1L | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.009); catalogued as COSV67721298; called by muse, mutect2, varscan2
- NALCN | c.3006G>C p.Q1002H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51938268, COSV99212640; called by muse, mutect2, varscan2
- NAPG | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV59797197; called by muse, mutect2, varscan2
- NBEAL2 | c.5457G>A p.L1819= | Splice Region (SNP) | VAF 2/10 reads (20%) | catalogued as rs1002565988; called by muse, mutect2
- NFKBIA | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as COSV53751515, COSV53752624; called by muse, mutect2, varscan2
- NLRC5 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1567540297, COSV52655973; called by muse, mutect2, varscan2
- NODAL | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs777283021, COSV54661544; called by muse, mutect2, varscan2
- NOL11 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV53523689; called by muse, mutect2, varscan2
- NOP9 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV51865901; called by muse, mutect2, varscan2
- NTF3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs374882330, COSV58417670; called by muse, mutect2, varscan2
- OGFRL1 | c.493A>T p.R165* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100965808; called by muse, mutect2, varscan2
- OR2B2 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100308234, COSV57579791; called by muse, mutect2, varscan2
- OR2J3 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV65849036; called by muse, mutect2, varscan2
- OR4F6 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV61026898; called by muse, mutect2, varscan2
- OR51B2 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs779676714, COSV60916797; called by muse, mutect2, varscan2
- OR6C75 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | catalogued as COSV100595463; called by muse, mutect2, varscan2
- OR6K3 | c.169G>C p.D57H (on ENST00000368146; = p.D41H on NM_001005327.2) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV63745690; called by muse, mutect2, varscan2
- OS9 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV57784520, COSV99233158; called by muse, mutect2
- PCNX3 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs964821940, COSV58419833; called by mutect2, varscan2
- PDE4A | c.1876G>C p.E626Q (on ENST00000380702 / NM_001111307.2; = p.E387Q on NM_006202.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53356536; called by muse, mutect2, varscan2
- PDE6C | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65116009; called by muse, mutect2, varscan2
- PDK1 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs996270562, COSV99961501; called by muse, mutect2, varscan2
- PDS5B | c.1495C>G p.Q499E | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1490922857, COSV59727604; called by muse, mutect2
- PGGHG | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV101164740; called by muse, mutect2
- PHAX | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52551328; called by muse, mutect2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, mutect2
- PITPNM2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54897209; called by muse, mutect2, varscan2
- PKD2L1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58396229; called by muse, mutect2, varscan2
- PKD2L1 | c.954G>A p.L318= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as rs762949037, COSV58396255, COSV58398270; called by mutect2, varscan2
- PKDREJ | c.2396G>C p.R799P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.222); catalogued as COSV53549611, COSV53554553; called by muse, mutect2, varscan2
- PPP1R13B | c.1938G>C p.E646D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.772); catalogued as COSV52451930; called by muse, mutect2, varscan2
- PPP2R2D | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70778809, COSV70778997; called by muse, mutect2, varscan2
- PPRC1 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | catalogued as rs549997961, COSV99532165; called by muse, mutect2, varscan2
- PRDX3 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100045461; called by muse, mutect2, varscan2
- PRKD1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1160777726, COSV59562884, COSV59575810; called by muse, mutect2
- PSMA8 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV100378887, COSV57602803; called by muse, mutect2, varscan2
- PYCR3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1168469742, COSV55306286, COSV55306469, COSV55308125; called by muse, mutect2, varscan2
- RAI14 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV54295281; called by muse, mutect2
- RANBP9 | c.1556C>G p.S519* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99163637; called by muse, mutect2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RBM7 | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100348459; called by muse, mutect2
- RBMXL2 | c.1103C>G p.S368* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100182512, COSV100182572; called by muse, mutect2, varscan2
- RHOBTB2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52570766, COSV52570983; called by muse, mutect2, varscan2
- RIPPLY2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63746589; called by muse, mutect2, varscan2
- RNF216 | c.2314G>C p.E772Q (on ENST00000425013 / NM_207116.3; = p.E829Q on NM_207111.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as COSV66290710; called by muse, mutect2, varscan2
- RNF216 | c.502G>A p.E168K (on ENST00000425013 / NM_207116.3; = p.E225K on NM_207111.4) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.023); catalogued as COSV66290714; called by muse, mutect2, varscan2
- RORB | c.1129G>T p.V377F (on ENST00000396204 / NM_001365023.1; = p.V366F on NM_006914.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65336304; called by muse, mutect2, varscan2
- RPL18A | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99714519; called by muse, mutect2, varscan2
- RPL32 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV56233036; called by muse, mutect2
- RRN3 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52213982; called by muse, mutect2
- RSRC2 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV59204696; called by muse, mutect2, varscan2
- RTN4 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.195); catalogued as COSV58268231; called by muse, mutect2, varscan2
- SBK1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1229438476, COSV59397149; called by muse, mutect2, varscan2
- SLC22A8 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV60325185; called by muse, mutect2, varscan2
- SLC26A11 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV63279708; called by muse, varscan2
- SLC26A11 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100755471; called by muse, varscan2
- SLIT2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs80248215, COSV56561255; called by muse, mutect2
- SMARCAL1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1302790588, COSV61921289; called by muse, mutect2
- SMARCC1 | c.2715G>C p.K905N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54381072; called by muse, varscan2
- SNX14 | c.2791G>A p.E931K (on ENST00000314673 / NM_001350535.1; = p.E878K on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59012328; called by muse, mutect2, varscan2
- SORCS1 | c.915A>T p.R305S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV53869730; called by muse, mutect2, varscan2
- SPRED1 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV54435409; called by muse, mutect2, varscan2
- SRC | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867805553, COSV62439971; called by muse, mutect2
- SRPK2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV61961290; called by muse, mutect2, varscan2
- SRRM4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); catalogued as COSV99939502; called by muse, mutect2
- STRIP2 | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50804585, COSV99973446; called by muse, mutect2, varscan2
- STXBP3 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); catalogued as COSV64182299; called by muse, mutect2, varscan2
- SUGP1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150375001, COSV55920804; called by muse, mutect2, varscan2
- SULF2 | c.1575G>C p.K525N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV63416495; called by muse, mutect2, varscan2
- SYCP2L | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV51653568, COSV51657507; called by muse, varscan2
- SYNE1 | c.18100G>A p.E6034K (on ENST00000367255 / NM_182961.4; = p.E5963K on NM_033071.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV54994369; called by muse, mutect2
- SYNPO2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100204655, COSV100206465; called by muse, mutect2, varscan2
- SYT1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54049842; called by muse, mutect2, varscan2
- TAF1L | c.3232C>G p.Q1078E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54262479; called by muse, mutect2, varscan2
- TERB2 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as rs1340153089, COSV61650876; called by muse, mutect2, varscan2
- TGFB1I1 | c.121C>T p.Q41* (on ENST00000394863 / NM_001042454.3; = p.Q24* on NM_015927.4) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100691249; called by mutect2, varscan2
- THBS2 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as COSV64679178; called by muse, varscan2
- THRAP3 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63567773, COSV63568013; called by muse, mutect2, varscan2
- THSD1 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51628792; called by muse, mutect2, varscan2
- THSD1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.869); catalogued as COSV51628811; called by muse, mutect2, varscan2
- TM4SF18 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV56058997; called by muse, mutect2
- TMEM215 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV104418137, COSV61363505; called by muse, mutect2
- TMEM234 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV59084548; called by muse, mutect2, varscan2
- TMEM63C | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV53604008; called by muse, mutect2, varscan2
- TNR | c.3219G>C p.L1073F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99691795; called by muse, mutect2
- TOR1AIP1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as rs548996424, COSV54871553; called by muse, mutect2
- TP53 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TRMT1L | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62272375; called by muse, mutect2, varscan2
- UBR4 | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64390526; called by muse, mutect2, varscan2
- UGGT1 | c.3600C>G p.F1200L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.338); catalogued as COSV52136267; called by muse, mutect2, varscan2
- ULK4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.609); catalogued as rs1438415841, COSV57210175; called by muse, mutect2, varscan2
- USP21 | c.631C>G p.H211D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV57089034; called by muse, mutect2
- UTP14C | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73000599, COSV73000677; called by muse, mutect2
- VIPAS39 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs746887391, COSV58939926; called by muse, mutect2, varscan2
- WAC | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV100611075, COSV61567693; called by muse, mutect2, varscan2
- WFDC3 | c.213G>T p.G71= | Splice Region (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99714832; called by muse, mutect2
- XRN2 | c.2740G>T p.G914W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65869736; called by mutect2, varscan2
- ZFAND3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV54726715; called by muse, mutect2, varscan2
- ZFYVE26 | c.7139G>A p.G2380E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as rs1380382407, COSV100720426, COSV61328953; called by muse, mutect2
- ZNF215 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53493251; called by muse, mutect2, varscan2
- ZNF343 | c.1631C>G p.S544* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99601669; called by muse, mutect2, varscan2
- ZNF432 | c.1183C>G p.H395D | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55416822; called by muse, mutect2, varscan2
- ZNF468 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 11/157 reads (7%) | catalogued as rs775090299, COSV99700866; called by muse, mutect2
- ZNF484 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100214907; called by muse, mutect2, varscan2
- ZNF582 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56732300; called by muse, mutect2, varscan2
- ZNF648 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs1462829731, COSV60570707, COSV60571228; called by muse, mutect2, varscan2
- ZNF846 | c.230-1G>C p.X77_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101194398; called by muse, mutect2
- GDF10 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- IGHG2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ACADS | c.195C>G p.L65= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV54369044; called by muse, varscan2
- ADAMTSL1 | c.3450C>T p.T1150= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1341991739, COSV65892688; called by muse, mutect2
- ADGRG6 | c.1185C>T p.N395= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99748881; called by muse, mutect2
- ANO2 | c.2304C>G p.L768= (on ENST00000356134 / NM_001278597.3; = p.L772= on NM_001278596.3) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV59024916; called by muse, mutect2, varscan2
- API5 | c.576T>A p.V192= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101124608; called by muse, mutect2
- ARID3B | c.1685G>A p.*562= (on ENST00000622429 / NM_001307939.1; = p.*561= on NM_006465.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100654775; called by muse, mutect2
- ASL | c.780C>A p.L260= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs143359899, COSV59188493; called by muse, mutect2, varscan2
- ATP11C | c.747G>A p.L249= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV59564687; called by muse, mutect2
- ATP1B1 | c.150C>T p.F50= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV63179373; called by muse, mutect2, varscan2
- BTBD3 | c.48G>A p.L16= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV54779436; called by muse, mutect2, varscan2
- CA9 | c.63C>T p.L21= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV65675773; called by muse, mutect2, varscan2
- CATIP | c.942C>T p.H314= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99179645; called by muse, mutect2
- CDK13 | c.2721C>G p.L907= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV51700339; called by muse, mutect2
- CES1 | c.987G>C p.L329= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV62085588, COSV62087176; called by muse, mutect2
- COCH | c.657G>A p.E219= (on ENST00000216361 / NM_001347720.1; = p.E154= on NM_004086.3) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs774069829, COSV53551098; called by muse, varscan2
- COL4A2 | c.4389G>C p.P1463= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV64628725; called by muse, mutect2, varscan2
- CSF2RB | c.1701C>T p.P567= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV53256472, COSV53258120; called by muse, mutect2, varscan2
- DEDD | c.708C>G p.L236= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs1326808574, COSV63501748; called by muse, mutect2, varscan2
- DEPDC5 | c.834C>T p.F278= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1364125679, COSV99836698; called by muse, mutect2
- EEFSEC | c.450C>G p.L150= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV54626228; called by muse, mutect2, varscan2
- ELF3 | c.204G>A p.S68= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs372289184; called by muse, mutect2, varscan2
- ELF3 | c.708G>A p.K236= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV62838469, COSV62839686; called by muse, mutect2, varscan2
- EPHA8 | c.1119G>A p.L373= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV51270164, COSV51270583; called by muse, mutect2
- FRY | c.4203G>A p.L1401= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV66564439, COSV66570867; called by muse, mutect2, varscan2
- GDF2 | c.1098C>T p.D366= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs781981224; called by muse, mutect2, varscan2
- GPER1 | c.294C>T p.F98= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV52469129; called by muse, mutect2
- GPER1 | c.912C>T p.L304= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV52467911; called by muse, mutect2, varscan2
- GRIK3 | c.1191G>A p.L397= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100902384, COSV66135743; called by muse, mutect2
- HSPA5 | c.1389C>T p.I463= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV52335597; called by muse, mutect2, varscan2
- KIF13B | c.4362C>G p.V1454= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV101342286; called by muse, mutect2
- KRT38 | c.1104C>T p.N368= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1350555072, COSV55846173; called by muse, mutect2, varscan2
- KRT4 | c.156C>T p.L52= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV53407548; called by muse, mutect2, varscan2
- LPO | c.390G>A p.V130= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99229458; called by muse, mutect2
- LRCH1 | c.585C>G p.V195= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV60847922; called by muse, mutect2, varscan2
- MAP3K10 | c.753C>T p.L251= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV53422650; called by muse, mutect2, varscan2
- MAST1 | c.1326G>A p.E442= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV52247656; called by muse, mutect2, varscan2
- MEFV | c.1299G>A p.L433= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV54822567; called by muse, mutect2, varscan2
- MEFV | c.153G>A p.V51= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1204951926, COSV54822585; called by muse, mutect2, varscan2
- MEOX2 | c.705C>T p.F235= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV56290278; called by muse, mutect2, varscan2
- MFAP3L | c.885G>A p.R295= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV64372262, COSV64372290; called by muse, mutect2, varscan2
- MICAL2 | c.4257G>A p.G1419= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56286242; called by muse, mutect2, varscan2
- MPDZ | c.5091G>A p.L1697= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV59918477; called by muse, mutect2, varscan2
- MYO1E | c.2619C>T p.F873= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs762581176, COSV55688145; called by muse, mutect2, varscan2
- MYOM1 | c.3045C>T p.N1015= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1167280865, COSV55292525; called by muse, mutect2, varscan2
- NAB2 | c.870G>A p.Q290= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs376864836; called by muse, mutect2, varscan2
- NAV3 | c.297G>A p.L99= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV57082547; called by muse, mutect2, varscan2
- NLRC4 | c.2757C>A p.L919= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV61592900, COSV61593355; called by muse, mutect2, varscan2
- OR2C3 | c.924G>A p.E308= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV63575116; called by muse, mutect2, varscan2
- OR2L2 | c.852C>G p.L284= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV63553462; called by muse, mutect2, varscan2
- P2RY14 | c.951G>A p.Q317= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV56380409; called by muse, mutect2, varscan2
- PARP12 | c.1209C>G p.V403= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54934543; called by muse, mutect2, varscan2
- PHF2 | c.3240G>A p.Q1080= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV63680161, COSV63681924; called by muse, mutect2, varscan2
- PI4KB | c.2289C>T p.F763= (on ENST00000368873 / NM_001369623.1; = p.F775= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99650219; called by muse, mutect2, varscan2
- PLXND1 | c.3420C>T p.F1140= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100140475; called by muse, mutect2
- RAB3IP | c.900C>T p.L300= (on ENST00000550536 / NM_175623.4; = p.L284= on NM_022456.5) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56083819, COSV99922850; called by muse, mutect2, varscan2
- RAB9A | c.364C>T p.L122= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV54610807; called by muse, mutect2, varscan2
- RACGAP1 | c.1758C>G p.L586= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV56699409; called by muse, mutect2, varscan2
- RUBCN | c.2529G>A p.L843= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56366877; called by muse, mutect2, varscan2
- RUVBL2 | c.672C>T p.F224= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs767682271, COSV55485438; called by muse, mutect2, varscan2
- SDHAF2 | c.420G>A p.L140= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV57099344; called by muse, mutect2, varscan2
- SMPD1 | c.1176C>T p.F392= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV54968337; called by muse, mutect2, varscan2
- SRCIN1 | c.2160G>A p.L720= (on ENST00000621492; = p.L686= on NM_025248.3) | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- SUSD5 | c.1347C>G p.L449= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs900905818, COSV58877964, COSV58880680; called by muse, mutect2, varscan2
- SYNRG | c.1245C>T p.L415= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- TNPO2 | c.156G>C p.L52= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV63510467; called by muse, mutect2
- TP53BP1 | c.2994G>A p.A998= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs45479696; called by muse, mutect2, varscan2
- TUBG1 | c.150C>G p.V50= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV52221282, COSV99258474; called by muse, mutect2, varscan2
- UTP14C | c.1302C>G p.L434= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV73000678, COSV73000829; called by muse, mutect2, varscan2
- UTP14C | c.1821C>T p.F607= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV73000645; called by muse, mutect2
- VPS72 | c.390G>C p.R130= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100614587; called by muse, mutect2
- WASHC2C | c.1854C>T p.F618= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100314250; called by muse, mutect2, varscan2
- WNT9B | c.618C>G p.L206= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV51518575; called by muse, mutect2, varscan2
- ZBTB12 | c.285C>T p.F95= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV64993874; called by muse, mutect2, varscan2
- ZC3H10 | c.1074G>A p.L358= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99230632; called by muse, mutect2
- ZNF585A | c.837C>T p.F279= (on ENST00000292841 / NM_001288800.2; = p.F224= on NM_152655.3) | Silent (SNP) | VAF 35/232 reads (15%) | catalogued as COSV53064086; called by muse, mutect2, varscan2
- FAF1 | c.1870-10596C>G | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- FBXL13 | c.496-5478C>G | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100502169; called by muse, mutect2, varscan2
- IKBIP | c.297+8168G>C | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as COSV54489305, COSV54489773; called by muse, mutect2
- MIR16-1 | n.87G>A | RNA (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7687C>T | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100521994, COSV57689637; called by muse, mutect2, varscan2
- RAPGEF1 | c.10+27769G>C | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as COSV64699825; called by muse, mutect2, varscan2
- SSPOP | n.14432C>T | RNA (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100948116; called by muse, mutect2
- TP63 | c.1350-6253G>A | Intron (SNP) | VAF 11/54 reads (20%) | catalogued as COSV53207542; called by muse, mutect2, varscan2
